Somatic mutation profile of tumor specimen TCGA-NH-A50T-01A (aliquot TCGA-NH-A50T-01A-11D-A28G-10) from TCGA case TCGA-NH-A50T, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Splenic flexure of colon; AJCC pathologic stage: Stage IIA; Age at diagnosis: 68.7 years (25,089 days).
Specimen TCGA-NH-A50T-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 39ba0d39-c448-46f7-96c5-3fcb646db8c2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-NH-A50T-10A (Blood Derived Normal), aliquot TCGA-NH-A50T-10A-01D-A28G-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c40ae20b-0a37-4178-86f3-46e87d7f1b3b

The open-access MAF lists 153 somatic variants for this specimen: 113 protein-altering or splice-affecting, 30 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 96, Silent 30, Nonsense Mutation 9, Intron 5, Frame Shift Ins 3, 5'UTR 2, Splice Region 2, Splice Site 2, 3'UTR 2, Frame Shift Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.502del p.R168Efs*2 | Frame Shift Del (DEL) | VAF 55/124 reads (44%) | catalogued as rs1554071602, COSV57320600; ClinVar: pathogenic; called by mutect2, varscan2
- FBXW7 | c.1394G>A p.R465H (on ENST00000281708 / NM_001349798.2; = p.R385H on NM_018315.5) | Missense Mutation (SNP) | VAF 117/142 reads (82%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519895, COSV55891746, COSV55897262, COSV55941157; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- MAP3K1 | c.3989C>T p.S1330L | Missense Mutation (SNP) | VAF 44/82 reads (54%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs1287268127, COSV68121509, COSV68122713; called by muse, mutect2, varscan2
- PIK3CA | c.311C>G p.P104R | Missense Mutation (SNP) | VAF 55/84 reads (65%) | hotspot (GDC flag); SIFT tolerated (0.1); PolyPhen benign (0.291); catalogued as COSV55878075, COSV55925758; called by muse, mutect2, varscan2
- ANKRD18A | c.124G>T p.A42S | Missense Mutation (SNP) | VAF 11/178 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); catalogued as COSV100890000; called by muse, mutect2
- APC | c.4164_4167dup p.V1390Ffs*6 | Frame Shift Ins (INS) | VAF 50/134 reads (37%) | catalogued as CI106657; called by mutect2, pindel, varscan2
- ARAF | c.1801G>A p.A601T | Missense Mutation (SNP) | VAF 24/115 reads (21%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.006); catalogued as COSV51691478; called by muse, mutect2, varscan2
- ARHGAP22 | c.365C>T p.A122V | Missense Mutation (SNP) | VAF 21/161 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as rs750730446, COSV99984848; called by muse, mutect2, varscan2
- ARHGEF17 | c.1535G>A p.G512D | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.001); catalogued as rs1034374422; called by muse, mutect2, varscan2
- AXIN1 | c.1244G>A p.R415H | Missense Mutation (SNP) | VAF 41/126 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as rs368340732; called by muse, mutect2, varscan2
- C10orf71 | c.287C>T p.A96V | Missense Mutation (SNP) | VAF 73/182 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs368058122, COSV100110672; called by muse, mutect2, varscan2
- CAB39L | c.988C>T p.R330* | Nonsense Mutation (SNP) | VAF 43/267 reads (16%) | catalogued as rs1254047124, COSV61713428; called by muse, mutect2, varscan2
- CNST | c.1720G>A p.D574N | Missense Mutation (SNP) | VAF 84/167 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs760612770, COSV100830101; called by muse, mutect2, varscan2
- COL4A1 | c.430G>A p.A144T | Missense Mutation (SNP) | VAF 114/172 reads (66%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs778175625; called by muse, mutect2
- CROCC | c.718C>T p.R240* | Nonsense Mutation (SNP) | VAF 45/205 reads (22%) | catalogued as rs779871764, COSV65011816; called by muse, mutect2, varscan2
- CRY2 | c.1316G>A p.R439H | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs767177340, COSV69888603; called by muse, mutect2, varscan2
- CSMD1 | c.4375C>A p.P1459T (on ENST00000520002; = p.P1458T on NM_033225.6) | Missense Mutation (SNP) | VAF 15/133 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59281958; called by muse, mutect2, varscan2
- DDHD2 | c.568C>T p.R190* | Nonsense Mutation (SNP) | VAF 34/223 reads (15%) | catalogued as rs377293194; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DLGAP2 | c.2594G>A p.R865H | Missense Mutation (SNP) | VAF 59/99 reads (60%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.997); catalogued as rs762572308, COSV101421736; called by muse, mutect2, varscan2
- DNAH5 | c.6884C>T p.A2295V | Missense Mutation (SNP) | VAF 35/101 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs368441809, COSV54235503; called by muse, mutect2, varscan2
- DNAJB12 | c.828C>T p.G276= (on ENST00000338820; = p.G242= on NM_017626.6 and 3 other RefSeq transcripts) | Splice Region (SNP) | VAF 34/83 reads (41%) | catalogued as rs766249452, COSV58760829; called by muse, mutect2, varscan2
- DSN1 | c.665G>A p.R222H | Missense Mutation (SNP) | VAF 26/165 reads (16%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.973); catalogued as rs761761654, COSV65519442; called by muse, mutect2, varscan2
- ECRG4 | c.427G>A p.V143I | Missense Mutation (SNP) | VAF 61/115 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs376920426, COSV53001310; called by muse, mutect2, varscan2
- FASN | c.4268G>A p.R1423H | Missense Mutation (SNP) | VAF 84/137 reads (61%) | SIFT tolerated (0.09); PolyPhen benign (0.206); catalogued as rs748110849, COSV60756581; called by muse, mutect2, varscan2
- FLRT2 | c.1954G>A p.V652M | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV58145198; called by muse, mutect2, varscan2
- FRMD8 | c.739G>A p.E247K | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.221); catalogued as rs745445330, COSV58212991; called by muse, mutect2, varscan2
- FRMPD3 | c.3637C>T p.R1213W | Missense Mutation (SNP) | VAF 9/190 reads (5%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as rs928954660, COSV52196309; called by muse, mutect2
- GIPC3 | c.638C>T p.A213V | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.611); catalogued as rs367979198; called by muse, varscan2
- GP5 | c.1276G>A p.D426N | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.962); catalogued as rs778829280, COSV59878752; called by muse, mutect2
- H3-5 | c.145C>T p.R49* | Nonsense Mutation (SNP) | VAF 66/174 reads (38%) | catalogued as COSV61187197; called by muse, mutect2
- HDAC2 | c.230T>C p.L77P | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64038590; called by muse, varscan2
- KCNK9 | c.607G>A p.G203R | Missense Mutation (SNP) | VAF 151/210 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs765113254, COSV57280031; called by muse, mutect2, varscan2
- KEL | c.32C>T p.P11L | Missense Mutation (SNP) | VAF 36/141 reads (26%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as rs747320273; called by muse, mutect2, varscan2
- KIAA1549L | c.2417C>T p.S806L (on ENST00000321505; = p.S1103L on NM_012194.3) | Missense Mutation (SNP) | VAF 52/84 reads (62%) | SIFT deleterious (0); PolyPhen benign (0.223); catalogued as rs201708570, COSV55775950; called by muse, mutect2, varscan2
- KIF6 | c.1229G>A p.S410N | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.482); catalogued as COSV54682282; called by muse, mutect2, varscan2
- KLK6 | c.679T>C p.Y227H | Missense Mutation (SNP) | VAF 36/317 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59565944; called by muse, mutect2, varscan2
- LAMA5 | c.4718G>A p.R1573H | Missense Mutation (SNP) | VAF 43/205 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs774677106, COSV53356578; called by muse, mutect2, varscan2
- LUZP2 | c.461C>A p.S154* | Nonsense Mutation (SNP) | VAF 36/120 reads (30%) | catalogued as COSV61194338; called by muse, mutect2, varscan2
- MFSD12 | c.500C>T p.T167M | Missense Mutation (SNP) | VAF 11/135 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs372325734; called by muse, mutect2
- MTMR1 | c.902C>T p.T301M | Missense Mutation (SNP) | VAF 47/212 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs1486439252, COSV64892436; called by muse, mutect2, varscan2
- MUC2 | c.161C>G p.T54S | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT tolerated, low confidence (0.76); catalogued as rs540847175; called by muse, mutect2, varscan2
- NFASC | c.1307G>A p.R436Q (on ENST00000339876 / NM_001378329.1; = p.R447Q on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/131 reads (15%) | SIFT tolerated (0.42); PolyPhen benign (0.247); catalogued as rs756666571, COSV58359751; called by muse, mutect2, varscan2
- NOTCH2 | c.7358G>A p.R2453Q | Missense Mutation (SNP) | VAF 29/110 reads (26%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.805); catalogued as rs145366664, COSV56683726; called by muse, mutect2, varscan2
- NTRK1 | c.1021G>A p.V341M | Missense Mutation (SNP) | VAF 159/278 reads (57%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs139875058; called by muse, mutect2, varscan2
- NUDT9 | c.113C>T p.S38L | Missense Mutation (SNP) | VAF 34/63 reads (54%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs752541554; called by muse, mutect2, varscan2
- OR51Q1 | c.364G>A p.V122I | Missense Mutation (SNP) | VAF 72/175 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs866002052, COSV56179996; called by muse, mutect2
- PALM2AKAP2 | c.548G>A p.R183H (on ENST00000374531 / NM_001037293.2; = p.R215H on NM_053016.6) | Missense Mutation (SNP) | VAF 40/101 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs780970261, COSV57118219, COSV57128894; called by muse, mutect2, varscan2
- PAPPA | c.1103C>T p.P368L | Missense Mutation (SNP) | VAF 46/95 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1291649850, COSV60281419; called by muse, mutect2, varscan2
- PCDH18 | c.1100C>T p.S367F | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.604); catalogued as COSV61266554; called by muse, mutect2, varscan2
- PCDHGB7 | c.113C>T p.P38L | Missense Mutation (SNP) | VAF 54/166 reads (33%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.67); catalogued as COSV53951803; called by muse, mutect2, varscan2
- PITPNA | c.527A>G p.N176S | Missense Mutation (SNP) | VAF 30/148 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as rs201928722, COSV57934781; called by muse, mutect2, varscan2
- PKLR | c.1088C>T p.A363V | Missense Mutation (SNP) | VAF 84/156 reads (54%) | SIFT tolerated (0.19); PolyPhen benign (0.079); catalogued as rs763466930, COSV100712874; called by muse, mutect2, varscan2
- POLR1A | c.4074T>G p.N1358K | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT tolerated (0.74); PolyPhen benign (0.003); catalogued as rs528582285; called by muse, varscan2
- POLR2B | c.356C>T p.T119M | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770511423, COSV100108028, COSV100108182; called by muse, mutect2, varscan2
- POM121L2 | c.880C>T p.R294W | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs779874635, COSV66276775; called by muse, mutect2, varscan2
- POP1 | c.1132G>A p.E378K | Missense Mutation (SNP) | VAF 36/81 reads (44%) | SIFT tolerated (0.29); PolyPhen benign (0.012); catalogued as rs772305728; called by muse, mutect2, varscan2
- PRDM5 | c.181C>T p.R61C | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs142855444; called by muse, mutect2, varscan2
- PSAT1 | c.748G>A p.V250I | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs368071286; called by muse, mutect2, varscan2
- RNF44 | c.232G>A p.G78R | Missense Mutation (SNP) | VAF 100/210 reads (48%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs575669062; called by muse, mutect2, varscan2
- ROBO2 | c.2219C>G p.P740R | Missense Mutation (SNP) | VAF 59/268 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59917638; called by muse, mutect2, varscan2
- SERINC4 | c.1429G>A p.V477I | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.101); catalogued as rs757496538, COSV99988248; called by muse, mutect2, varscan2
- STAB1 | c.5495G>A p.R1832Q | Missense Mutation (SNP) | VAF 43/149 reads (29%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.782); catalogued as rs569332503; called by muse, mutect2, varscan2
- STOM | c.572G>A p.R191H | Missense Mutation (SNP) | VAF 43/140 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763192503; called by muse, mutect2, varscan2
- SYNE1 | c.11791C>A p.L3931I | Missense Mutation (SNP) | VAF 23/109 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV55097304; called by muse, mutect2, varscan2
- TDRD15 | c.4654A>T p.I1552F | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.347); catalogued as rs527812154, COSV68267593; called by muse, mutect2, varscan2
- TP53BP1 | c.4345C>T p.R1449* | Nonsense Mutation (SNP) | VAF 65/124 reads (52%) | catalogued as rs1201648831, COSV55507976; called by muse, mutect2, varscan2
- UTP23 | c.400G>C p.G134R | Missense Mutation (SNP) | VAF 22/129 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.448); catalogued as COSV59124546; called by muse, mutect2, varscan2
- VSTM4 | c.182G>A p.R61H | Missense Mutation (SNP) | VAF 41/167 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs144984771; called by muse, mutect2, varscan2
- WNK2 | c.3109G>A p.A1037T | Missense Mutation (SNP) | VAF 36/69 reads (52%) | SIFT tolerated (0.25); PolyPhen benign (0.06); catalogued as rs1226219733; called by muse, mutect2, varscan2
- ZNF773 | c.235G>T p.E79* | Nonsense Mutation (SNP) | VAF 54/141 reads (38%) | catalogued as COSV56589107; called by muse, mutect2, varscan2
- ABCA13 | c.3741dup p.L1248Tfs*2 | Frame Shift Ins (INS) | VAF 16/114 reads (14%) | called by mutect2, varscan2
- ANKRD12 | c.1583_1587dup p.D530Kfs*23 | Frame Shift Ins (INS) | VAF 20/58 reads (34%) | called by mutect2, pindel, varscan2
- ANOS1 | c.1564C>T p.P522S | Missense Mutation (SNP) | VAF 118/202 reads (58%) | SIFT tolerated (0.52); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ASPM | c.3046C>G p.L1016V | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ATAD5 | c.401T>C p.I134T | Missense Mutation (SNP) | VAF 14/21 reads (67%) | SIFT deleterious (0.02); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- C2orf78 | c.1260T>A p.N420K | Missense Mutation (SNP) | VAF 42/141 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CDCA5 | c.47-3C>T | Splice Region (SNP) | VAF 12/20 reads (60%) | called by muse, mutect2, varscan2
- EP300 | c.1282+3_1282+31del p.X428_splice | Splice Site (DEL) | VAF 12/42 reads (29%) | called by mutect2, pindel, varscan2
- ETAA1 | c.2245A>C p.N749H | Missense Mutation (SNP) | VAF 72/110 reads (65%) | SIFT deleterious (0.03); PolyPhen benign (0.095); called by muse, mutect2
- FAM120C | c.1431A>C p.E477D | Missense Mutation (SNP) | VAF 34/212 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FAM83G | c.2462A>G p.K821R | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.321); called by mutect2, varscan2
- FOLH1 | c.50G>A p.R17H | Missense Mutation (SNP) | VAF 45/124 reads (36%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- FOS | c.161C>T p.A54V | Missense Mutation (SNP) | VAF 41/129 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- HAPLN4 | c.787G>A p.D263N | Missense Mutation (SNP) | VAF 60/136 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- HTATSF1 | c.217G>A p.A73T | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- IRX1 | c.1322T>A p.L441H | Missense Mutation (SNP) | VAF 68/152 reads (45%) | SIFT tolerated (0.54); PolyPhen benign (0.293); called by muse, mutect2, varscan2
- KBTBD7 | c.172G>A p.D58N | Missense Mutation (SNP) | VAF 226/314 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KCNH3 | c.1259G>A p.G420E | Missense Mutation (SNP) | VAF 28/139 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- KCTD8 | c.667A>G p.N223D | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.306); called by muse, mutect2, varscan2
- KHDC1 | c.170A>G p.N57S | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.299); called by muse, mutect2, varscan2
- KLHL14 | c.1407C>A p.H469Q | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- KLHL5 | c.1916C>T p.A639V | Missense Mutation (SNP) | VAF 60/120 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); called by muse, varscan2
- LCP2 | c.1524G>T p.M508I | Missense Mutation (SNP) | VAF 25/168 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- LRP12 | c.1454G>A p.C485Y | Missense Mutation (SNP) | VAF 28/240 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- LRRN1 | c.258G>T p.K86N | Missense Mutation (SNP) | VAF 56/154 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- MAN2B1 | c.2406C>A p.S802R | Missense Mutation (SNP) | VAF 26/129 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MAPT | c.1640G>A p.R547Q (on ENST00000262410 / NM_001377265.1; = p.R155Q on NM_005910.5) | Missense Mutation (SNP) | VAF 157/215 reads (73%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDHA1 | c.1514C>A p.S505* | Nonsense Mutation (SNP) | VAF 56/250 reads (22%) | called by muse, mutect2, varscan2
- PCSK5 | c.1922G>A p.S641N | Missense Mutation (SNP) | VAF 51/120 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- PEX11G | c.349G>C p.V117L | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT tolerated (0.45); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PLXNC1 | c.2428G>T p.A810S | Missense Mutation (SNP) | VAF 49/118 reads (42%) | SIFT tolerated (0.28); PolyPhen benign (0.228); called by muse, mutect2, varscan2
- PROZ | c.190G>C p.V64L | Missense Mutation (SNP) | VAF 25/138 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- PTPRG | c.3445C>T p.R1149* | Nonsense Mutation (SNP) | VAF 43/190 reads (23%) | called by muse, mutect2, varscan2
- SEC14L1 | c.732C>G p.I244M | Missense Mutation (SNP) | VAF 156/255 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- TP53BP1 | c.4085+1G>A p.X1362_splice | Splice Site (SNP) | VAF 30/65 reads (46%) | called by muse, mutect2, varscan2
- TRIM39 | c.1247G>A p.R416Q | Missense Mutation (SNP) | VAF 63/107 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRPS1 | c.1648T>C p.Y550H (on ENST00000220888 / NM_001330599.2; = p.Y563H on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 122/167 reads (73%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- VCAM1 | c.1837G>T p.V613F | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- VCAN | c.4851A>C p.E1617D | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- VSIG4 | c.615C>G p.D205E | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.712); called by muse, mutect2, varscan2
- VWF | c.2693G>T p.C898F | Missense Mutation (SNP) | VAF 75/155 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- WNK3 | c.2379C>G p.N793K | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.468); called by muse, mutect2, varscan2
- WNT3 | c.551C>T p.S184L | Missense Mutation (SNP) | VAF 37/170 reads (22%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.453); called by muse, mutect2, varscan2
- ACKR4 | c.324G>A p.G108= | Silent (SNP) | VAF 152/257 reads (59%) | catalogued as COSV99391450; called by muse, varscan2
- ANKRD27 | c.2184G>A p.A728= | Silent (SNP) | VAF 61/171 reads (36%) | catalogued as rs1273420535; called by muse, mutect2, varscan2
- ARNT2 | c.1821G>A p.P607= | Silent (SNP) | VAF 85/168 reads (51%) | catalogued as rs377099665; called by muse, mutect2
- BNC2 | c.2841C>T p.N947= | Silent (SNP) | VAF 87/195 reads (45%) | catalogued as rs1195684672; called by muse, mutect2, varscan2
- BOC | c.1623C>T p.P541= | Silent (SNP) | VAF 36/199 reads (18%) | catalogued as rs764762676, COSV56350648; called by muse, mutect2, varscan2
- CBLL2 | c.333C>A p.V111= | Silent (SNP) | VAF 23/115 reads (20%) | called by muse, mutect2, varscan2
- CEP350 | c.8598G>A p.A2866= | Silent (SNP) | VAF 91/190 reads (48%) | catalogued as rs562548913, COSV62604578; called by muse, mutect2, varscan2
- CHL1 | c.747A>C p.S249= (on ENST00000397491 / NM_001253387.1; = p.S265= on NM_006614.4) | Silent (SNP) | VAF 59/129 reads (46%) | called by muse, mutect2, varscan2
- COL20A1 | c.1239C>T p.A413= | Silent (SNP) | VAF 23/187 reads (12%) | catalogued as COSV58919621; called by muse, mutect2, varscan2
- DGKD | c.2052G>A p.P684= (on ENST00000264057 / NM_152879.3; = p.P640= on NM_003648.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 73/174 reads (42%) | catalogued as rs370757617, COSV51047421, COSV99897866; called by muse, mutect2, varscan2
- FERD3L | c.438C>A p.A146= | Silent (SNP) | VAF 39/313 reads (12%) | called by muse, mutect2, varscan2
- GLCE | c.1134G>A p.K378= | Silent (SNP) | VAF 48/106 reads (45%) | called by muse, mutect2, varscan2
- GPM6A | c.258C>T p.Y86= | Silent (SNP) | VAF 22/87 reads (25%) | catalogued as rs747238866; called by muse, mutect2, varscan2
- GREB1 | c.816G>A p.P272= | Silent (SNP) | VAF 63/103 reads (61%) | catalogued as rs368334075; called by muse, mutect2, varscan2
- GTF2IRD2B | c.1731C>T p.S577= | Silent (SNP) | VAF 78/853 reads (9%) | catalogued as rs782509948, COSV100441174; called by muse, varscan2
- KCNJ3 | c.276C>G p.T92= | Silent (SNP) | VAF 70/335 reads (21%) | catalogued as COSV54538839, COSV54547915; called by muse, mutect2, varscan2
- KRT3 | c.1296C>T p.I432= | Silent (SNP) | VAF 66/128 reads (52%) | catalogued as rs376783753; called by muse, mutect2, varscan2
- MAGEC2 | c.177T>C p.S59= | Silent (SNP) | VAF 32/54 reads (59%) | called by muse, mutect2, varscan2
- MOGAT2 | c.480G>A p.L160= | Silent (SNP) | VAF 48/164 reads (29%) | called by muse, mutect2, varscan2
- MRPL49 | c.285C>T p.P95= | Silent (SNP) | VAF 38/93 reads (41%) | catalogued as rs749795286; called by muse, mutect2, varscan2
- NKX6-2 | c.756G>A p.T252= | Silent (SNP) | VAF 39/208 reads (19%) | called by muse, mutect2, varscan2
- OR7D2 | c.537C>T p.C179= | Silent (SNP) | VAF 37/105 reads (35%) | catalogued as rs560821814, COSV60139025; called by muse, mutect2
- POP1 | c.441C>T p.N147= | Silent (SNP) | VAF 18/109 reads (17%) | catalogued as rs370950344; called by mutect2, varscan2
- PPP1R8 | c.333C>T p.I111= | Silent (SNP) | VAF 87/143 reads (61%) | catalogued as rs564749187; called by muse, mutect2, varscan2
- SOX3 | c.393C>T p.G131= | Silent (SNP) | VAF 50/77 reads (65%) | called by muse, mutect2, varscan2
- SPANXB1 | c.24C>T p.R8= | Silent (SNP) | VAF 264/2257 reads (12%) | called by muse, varscan2
- SPDYC | c.837C>T p.Y279= | Silent (SNP) | VAF 16/44 reads (36%) | called by muse, mutect2, varscan2
- TPD52L2 | c.552C>T p.N184= | Silent (SNP) | VAF 25/158 reads (16%) | catalogued as rs760830329, COSV53862718; called by muse, mutect2, varscan2
- TRIM42 | c.498C>T p.C166= | Silent (SNP) | VAF 85/136 reads (63%) | catalogued as rs756270365, COSV53879972; called by muse, mutect2, varscan2
- WDR64 | c.177G>A p.S59= | Silent (SNP) | VAF 112/340 reads (33%) | catalogued as rs779123467; called by muse, mutect2, varscan2
- AC132217.2 | c.*46+1205G>A | Intron (SNP) | VAF 19/33 reads (58%) | catalogued as rs757811186, COSV56099805; called by muse, mutect2, varscan2
- CNTNAP3P2 | n.993T>C | RNA (SNP) | VAF 21/217 reads (10%) | catalogued as rs757459349; called by muse, mutect2, varscan2
- ERICH3 | c.603+1597G>T | Intron (SNP) | VAF 28/61 reads (46%) | catalogued as COSV100443214; called by muse, mutect2, varscan2
- FUNDC2 | c.133+288C>A | Intron (SNP) | VAF 12/23 reads (52%) | catalogued as rs1028664677; called by muse, mutect2, varscan2
- HSPB7 | c.-30C>T | 5'UTR (SNP) | VAF 25/73 reads (34%) | catalogued as rs989002739, COSV100317758; called by muse, mutect2, varscan2
- PML | c.1710+876C>T | Intron (SNP) | VAF 37/105 reads (35%) | called by muse, mutect2, varscan2
- PRDX4 | c.476+58T>C | Intron (SNP) | VAF 33/209 reads (16%) | called by muse, mutect2, varscan2
- SNN | c.*1011C>A | 3'UTR (SNP) | VAF 58/68 reads (85%) | catalogued as COSV99297198; called by mutect2, varscan2
- SPRY3 | c.*2371C>T | 3'UTR (SNP) | VAF 53/97 reads (55%) | catalogued as COSV100249121; called by muse, mutect2, varscan2
- TBCA | c.-18C>T | 5'UTR (SNP) | VAF 89/205 reads (43%) | catalogued as rs1251955612, COSV100115808; called by muse, mutect2, varscan2
